CCDI case PBBXGC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2163f559-2406-49e7-9c9a-7143f01252a2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.6 years (1,310 days).

Biospecimens (3 samples)
- Sample 0DJO4U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJO59: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJO5M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
